FM case AD14251 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/5e00d0c5-1ed9-4282-932a-b2ebd68d05cc

Female, 69.9 years: Duct adenocarcinoma, NOS (ICD-O-3 8500/3) of the pancreas; metastasis. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
